MMRF case MMRF_2409 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2e1e1105-9a63-46c0-b50c-9c215383281f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.9 years (24,436 days); ISS stage: I; Days to last known disease status: 785 days (2.1 years); Days to last follow up: 785 days (2.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 135 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 176 days; Days to treatment end: 176 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 178 days; Days to treatment end: 178 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 345 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 2.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.576 mg/dL; Immunoglobulin G 3.79 g/L; Immunoglobulin A 31.5 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 2.9 µg/mL; Lactate Dehydrogenase 3.75 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 373 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.45 mmol/L; Albumin 38 g/L; Total Protein 9.8 g/dL; Glucose 4.51 mmol/L; C-Reactive Protein 0.12 mg/dL.
- Day 106 (ECOG 1): M Protein 0.172 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.939 mg/dL; Immunoglobulin G 3.63 g/L; Immunoglobulin A 3.38 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 10.2 mmol/L.
- Day 212 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.469 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.678 mg/dL; Immunoglobulin G 6.24 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.44 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.35 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 7.48 mmol/L.
- Day 277 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.273 mg/dL; Immunoglobulin G 6.65 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 5.45 mmol/L.
- Day 338 (ECOG 1): Immunoglobulin G 6.5 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 15.7 mmol/L.
- Day 429 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin G 7.27 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.76 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 13.5 mmol/L.
- Day 526 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.04 mg/dL; Immunoglobulin G 8.31 g/L; Immunoglobulin A 2.25 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 9.74 mmol/L.
- Day 613 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.95 mg/dL; Immunoglobulin G 7.82 g/L; Immunoglobulin A 2.46 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 10.1 mmol/L.
- Day 704 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.16 mg/dL; Immunoglobulin G 8.81 g/L; Immunoglobulin A 3.03 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 6.22 mmol/L.
- Day 785 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.75 mg/dL; Immunoglobulin G 9.82 g/L; Immunoglobulin A 3.09 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.39 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 9.02 mmol/L.

Other clinical attributes
- Day 1: Weight: 102 kg; Height: 170 cm.

Biospecimens (2 samples)
- Sample MMRF_2409_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2409_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
